Somatic mutation profile of tumor specimen C3N-02770-08 (aliquot CPT0205670007) from CPTAC case C3N-02770, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.5 years (25,753 days).
Specimen C3N-02770-08: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5cd6b9f-8195-4807-bcb4-6114ac37fa27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02770-71 (Blood Derived Normal), aliquot CPT0205730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4ada5f1-ebce-4905-874c-836e11cd85dd

The open-access MAF lists 70 somatic variants for this specimen: 42 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 19, Nonsense Mutation 3, 3'UTR 3, Intron 2, RNA 2, Frame Shift Ins 2, Splice Site 1, Splice Region 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 488/10346 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1164954595, COSV51779091, COSV51843270; called by muse, mutect2
- CCDC168 | c.5066C>T p.T1689M | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs796497841; called by muse, mutect2, varscan2
- CFAP44 | c.1568T>C p.M523T | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs766825874, COSV55617435; called by muse, mutect2, varscan2
- EGFR | c.1883G>A p.C628Y | Missense Mutation (SNP) | VAF 5708/7434 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51840469, COSV51851464; called by mutect2, varscan2
- EPB41L3 | c.3125C>T p.T1042M | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147930423; called by muse, mutect2, varscan2
- F5 | c.6305G>A p.R2102H | Missense Mutation (SNP) | VAF 177/474 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM020107; called by muse, mutect2, varscan2
- FGB | c.115-7C>T | Splice Region (SNP) | VAF 83/196 reads (42%) | catalogued as rs1160791508; called by muse, mutect2, varscan2
- GET3 | c.44T>C p.F15S | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs750853138; called by muse, varscan2
- GPR39 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.909); catalogued as rs1378454923; called by muse, mutect2, varscan2
- KRT34 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 191/516 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs759197812; called by muse, mutect2, varscan2
- LTF | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 75/189 reads (40%) | catalogued as rs763788330, COSV51607173; called by muse, mutect2, varscan2
- MXRA5 | c.8242G>A p.G2748R | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54255869; called by muse, mutect2, varscan2
- NPAP1 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 108/260 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201894790, COSV61505775; called by muse, mutect2, varscan2
- NUSAP1 | c.524dup p.N175Kfs*2 | Frame Shift Ins (INS) | VAF 62/237 reads (26%) | catalogued as rs775467155; called by mutect2, pindel, varscan2
- OR52M1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1003014199, COSV64171793; called by muse, mutect2, varscan2
- OR5D14 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 100/257 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1203752020, COSV59455376; called by muse, mutect2, varscan2
- OTULIN | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.466); catalogued as rs867617260; called by muse, mutect2, varscan2
- PAG1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs141088766; called by muse, mutect2, varscan2
- PAX1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 288/1097 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV68271544; called by muse, mutect2, varscan2
- PCLO | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs767073368; called by muse, mutect2
- RYR1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 175/463 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs748318655, COSV100615705, COSV62107125; called by muse, mutect2, varscan2
- TMPRSS11A | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 95/288 reads (33%) | catalogued as rs539520672, COSV58357418, COSV58361151; called by muse, mutect2, varscan2
- TTN | c.34909G>A p.V11637I (on ENST00000591111; = p.V10710I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/383 reads (38%) | PolyPhen benign (0); catalogued as rs374394719; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- XIRP1 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371304146; called by muse, mutect2, varscan2
- ZNF469 | c.3794C>T p.S1265L (on ENST00000437464; = p.S1293L on NM_001367624.2) | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs994408836; called by muse, mutect2, varscan2
- ABCA3 | c.4198G>A p.D1400N | Missense Mutation (SNP) | VAF 136/358 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANO3 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CGAS | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- COL14A1 | c.4484G>C p.G1495A | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPY19L2 | c.1174A>C p.M392L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FBXO43 | c.1837_1850dup p.L617Ffs*6 | Frame Shift Ins (INS) | VAF 32/138 reads (23%) | called by mutect2, varscan2
- HCN1 | c.2261A>T p.Q754L | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRM1 | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- MSS51 | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 143/373 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- MYB | c.1780A>G p.N594D | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.071); called by muse, varscan2
- NHLRC3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- POTEF | c.1159_1160insGA p.S387* | Nonsense Mutation (INS) | VAF 28/229 reads (12%) | called by pindel, varscan2
- REP15 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31D1 | c.3964C>G p.P1322A | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYCP1 | c.2044-1G>A p.X682_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- TUSC3 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ZNF747 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2
- BSN | c.81C>A p.P27= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- CLEC12B | c.501C>T p.N167= | Silent (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- CYLC2 | c.567C>T p.N189= | Silent (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- GRM8 | c.2163C>A p.I721= | Silent (SNP) | VAF 6/143 reads (4%) | called by muse, mutect2
- GUK1 | c.381G>T p.L127= | Silent (SNP) | VAF 21/235 reads (9%) | called by muse, mutect2
- HECTD4 | c.1806G>A p.A602= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as rs369071740; called by muse, mutect2, varscan2
- IGHV4-28 | c.312T>C p.S104= | Silent (SNP) | VAF 222/580 reads (38%) | called by muse, varscan2
- ITGB2 | c.816C>T p.D272= | Silent (SNP) | VAF 21/196 reads (11%) | catalogued as rs779979379, COSV56611395; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITPK1 | c.186C>T p.D62= | Silent (SNP) | VAF 81/264 reads (31%) | catalogued as rs541218411; called by muse, mutect2, varscan2
- LLGL2 | c.2682C>T p.D894= | Silent (SNP) | VAF 89/208 reads (43%) | catalogued as rs377098784; called by muse, mutect2, varscan2
- LRRK2 | c.4713C>T p.H1571= | Silent (SNP) | VAF 81/231 reads (35%) | catalogued as rs778987251, COSV54142249; called by muse, mutect2, varscan2
- NFAT5 | c.336G>C p.V112= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs1166261719; called by muse, mutect2, varscan2
- OR5K4 | c.369T>C p.Y123= | Silent (SNP) | VAF 133/370 reads (36%) | called by muse, mutect2, varscan2
- PDE1C | c.1626C>T p.A542= | Silent (SNP) | VAF 121/454 reads (27%) | catalogued as rs371391797; called by muse, mutect2, varscan2
- PGRMC1 | c.102G>T p.L34= | Silent (SNP) | VAF 214/264 reads (81%) | called by muse, mutect2, varscan2
- SH2D5 | c.312T>C p.F104= (on ENST00000444387 / NM_001103161.2; = p.F20= on NM_001103160.2) | Silent (SNP) | VAF 128/342 reads (37%) | catalogued as rs980029046; called by muse, mutect2, varscan2
- TPSB2 | c.825G>A p.P275= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs753650266, COSV99326694; called by muse, mutect2, varscan2
- WAS | c.264C>T p.Y88= | Silent (SNP) | VAF 109/134 reads (81%) | catalogued as rs150520117, CM972882; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ZNF329 | c.18G>A p.T6= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs769976463; called by muse, mutect2, varscan2
- ARPP19P1 | n.31G>A | RNA (SNP) | VAF 92/216 reads (43%) | called by muse, mutect2
- EFHC1 | c.*2767C>A | 3'UTR (SNP) | VAF 50/160 reads (31%) | called by muse, mutect2, varscan2
- EIF2S1 | c.*9G>T | 3'UTR (SNP) | VAF 166/465 reads (36%) | called by muse, mutect2, varscan2
- NF1 | chr17:31381954 T>A | 3'Flank (SNP) | VAF 59/166 reads (36%) | called by muse, mutect2, varscan2
- NOP16 | c.*76G>A | 3'UTR (SNP) | VAF 77/198 reads (39%) | catalogued as rs768223824; called by muse, mutect2, varscan2
- OOSP2 | c.-11C>T | 5'UTR (SNP) | VAF 35/305 reads (11%) | catalogued as rs375512065; called by muse, mutect2, varscan2
- RIT1 | c.-43-80T>C | Intron (SNP) | VAF 146/435 reads (34%) | called by muse, mutect2, varscan2
- SPTA1 | c.6788+11C>T | Intron (SNP) | VAF 69/178 reads (39%) | catalogued as rs779537034, COSV63750467; called by muse, mutect2, varscan2
- TBC1D27P | n.1643C>G | RNA (SNP) | VAF 38/110 reads (35%) | catalogued as rs1036899633; called by muse, mutect2, varscan2
